Somatic mutation profile of tumor specimen TCGA-HT-A74J-01A (aliquot TCGA-HT-A74J-01A-12D-A32B-08) from TCGA case TCGA-HT-A74J, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 33.9 years (12,393 days).
Specimen TCGA-HT-A74J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53b3ad35-ea14-402f-8b2d-8e38afa53b14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A74J-10A (Blood Derived Normal), aliquot TCGA-HT-A74J-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8da1f31-6aa4-43e2-acbe-c98f710249d8

The open-access MAF lists 24 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 3, Nonsense Mutation 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.2719C>T p.R907* | Nonsense Mutation (SNP) | VAF 144/174 reads (83%) | hotspot (GDC flag); catalogued as COSV64870748; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 31/61 reads (51%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 22/30 reads (73%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACO2 | c.1474T>C p.S492P | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99347782; called by muse, mutect2, varscan2
- ANKRD46 | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); catalogued as COSV100170266; called by muse, mutect2
- ARFGEF2 | c.5068T>C p.C1690R | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV100904498; called by muse, mutect2
- CACNA1G | c.6548G>A p.S2183N | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV61730111; called by muse, mutect2
- COA6 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.18); catalogued as COSV100784619; called by muse, mutect2, varscan2
- CTNNB1 | c.1082-2A>G p.X361_splice | Splice Site (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100846514; called by muse, mutect2, varscan2
- CTSW | c.929A>C p.E310A | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV100327562; called by muse, mutect2, varscan2
- HNF4A | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs147342965, COSV57388658; called by muse, mutect2
- LRRC43 | c.1592C>T p.T531M | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as rs780825256, COSV60293651; called by muse, mutect2, varscan2
- MAP4 | c.1724A>G p.D575G | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as COSV100806379; called by muse, mutect2, varscan2
- MIA3 | c.4447T>C p.S1483P | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100485240; called by muse, mutect2, varscan2
- NEK5 | c.722A>C p.Q241P | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100839310; called by muse, mutect2
- NOP58 | c.1360A>G p.I454V | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99970870; called by muse, mutect2
- ST3GAL4 | c.856G>A p.A286T (on ENST00000392669 / NM_001254758.1; = p.A282T on NM_006278.3) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs550860098, COSV99917717; called by muse, mutect2, varscan2
- TRIM56 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs1466721690, COSV100047790, COSV60158420, COSV60159256; called by muse, mutect2, varscan2
- USP48 | c.2969G>A p.G990D | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV100380275; called by muse, mutect2, varscan2
- ZDBF2 | c.4625A>G p.D1542G | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.721); catalogued as COSV100985582, COSV65628850; called by muse, mutect2, varscan2
- DHCR7 | c.417T>G p.V139= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV100832153; called by muse, mutect2
- PDE10A | c.285G>C p.R95= | Silent (SNP) | VAF 64/162 reads (40%) | catalogued as COSV100605864, COSV63103312; called by muse, mutect2, varscan2
- PHKA2 | c.3306T>A p.G1102= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV101177489; called by muse, mutect2, varscan2
- AGAP7P | n.923T>G | RNA (SNP) | VAF 28/422 reads (7%) | called by muse, mutect2
